Surgical pathology report (de-identified scan), TCGA case TCGA-2G-AAG7, project TCGA-TGCT (Testicular Germ Cell Tumors), tissue source site Erasmus MC, specimen TCGA-2G-AAG7-01A (Primary Tumor).

Department of Pathology

Direct dial

Mobile:

Internal postal address

E-mail

Date

Concerning

Postal address

Street address

Summary pathology report

20% 20% pNTSS

Left orchidectomy; nonseminoma (EC 40%, MT plus IT together 40%; YST 20%) diameter 1.5 cm; tumor confined to testis; no angio-invasion; no invasion of rete testis.

Date of procurement (= date of orchidectomy):

pathologist

professor of pathology

ICD-O-3
Mixed germ cell tumor
9085/3
Site @ Testis NOS
0629
9/23/7/14

Source: NCI Genomic Data Commons file ef2a7719-fd4f-4984-8f35-f29763ad6345 (TCGA-2G-AAG7.D356C346-2AD4-4F4E-9419-EA3F1D0DE68C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).